Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6407, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6407-02B (Recurrent Tumor).

[page 1 of 3]
Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final I

Patient Name:
DOB/Age/Gender:
Location: Responsible Staff:

MRN:

Female Provider:

Service Date/Time:

ICD O-3
Glioblastoma multiforme
09440/3
Site ^{OSCE} Spinal cord C72.0
Path
Brain NOS 871.9
9/30/13

Surgical Pathology Report

Patient Name:

Accession #:

Med: Rec.:

Phone Number:

DOB:

Gender: F

Client:

Taken:

Received:

Reported:

Physician(s):

Phy Location:

CLINICAL HISTORY

The patient is a -year-old woman who had an oligodendroglioma diagnosed in and recurrence on . Currently she has nodular contrast-enhancing progressive disease.

OPERATIVE DIAGNOSES

Possible recurrent tumor

Operation/Specimen: A: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, right temporal lesion, excision: Glioblastoma with oligodendroglial component (WHO Grade IV) (see comment).

COMMENT

Sections show a densely cellular pleomorphic glioma demonstrating frequent mitotic figures and pseudopalisading necrosis. The tumor cell nuclei are hyperchromatic and irregularly shaped, and mostly resemble those found in glioblastoma. The prior oligodendroglial phenotype of the tumor cells is not clearly recognizable on permanent sections, however mini-gemistocytic type cytoplasm can be observed in some of the tumor cells and a small fraction of the tumor cell nuclei are roughly round in shape. The latter can also be seen in the intraoperative smear preparations. The tumor is focally GFAP positive, but largely negative. The tumor is also weakly NeuN positive and shows focal synaptophysin positivity. The patient's prior specimen is reviewed and confirmed to show mixed oligodendroglial and astrocytic histological features. At that time the Ki-67 labeling index of the tumor was approximately

5 to 15%. The current specimen shows little resemblance to the specimen histologically and demonstrates a much higher Ki-67 labeling index of 80 to 90%. This likely reflects transformation of the prior lesion to glioblastoma. An immunohistochemical stain for p53 is strongly and diffusely positive. Nearly 100% of the tumor cells demonstrate strong nuclear immunoreactivity. The Ki-67 labeling index is 80 to 90%.

The MGMT promoter methylation assay is now negative, and partial loss of chromosome arm 1p is detected without evidence of 19q loss (see procedures/addenda below).

Electronically Signed Out

, Senior Staff Pathologist

[page 2 of 3]
=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on tissue block (A3).

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Consultant:

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

There is loss of heterozygosity at D1S548 locus suggestive of partial loss on chromosome arm 1p

There is no allelic loss on chromosome arm 19q detected.

Informative loci are: D1S548, D1S552, D19S219, D19S412, PLA2G4C and D19S606

Results-Comments

Testing performed on DNA extracted from a paraffin tumor block

(A3)

and a corresponding blood specimen.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 3 of 3]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, excision biopsy, touch prep and smears: Oligodendroglioma, anaplastic.

. Touch preparation smears performed at and results reported to the Physician of Record.

, Senior Staff Pathologist

GROSS DESCRIPTION

A.

Received fresh, several fragments, 2 x 2 x 0.4 cm. in aggregate. Diffluent, grayish, translucent. In total, A1-A3.

ICD-9(s):

239.6 239.6

Billing Fee Code(s):

A:

LOH

MGMT:

Histo Data

Part A: Brain, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H/E x 1 1

TPS H/E x 1 1

H/E x 1 2

mGFAP-DA x 1 3

H/E x 1 3

MGMT x 1 3

MIB1-DA x 1 3

NeuN x 1 3

P53DO7 x 1 3

Synap-DA x 1 3

*** End of Report ***

Diagnosis Discrepancy	lu 7/31/13	

Source: NCI Genomic Data Commons file f2db35d9-54fd-449c-a8cd-2c933ed4a39a (TCGA-DU-6407.49BAF246-AE0A-4627-AF91-35932D00F105.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).